Somatic mutation profile of tumor specimen TCGA-QQ-A8VF-01A (aliquot TCGA-QQ-A8VF-01A-11D-A37C-09) from TCGA case TCGA-QQ-A8VF, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 70.3 years (25,682 days).
Specimen TCGA-QQ-A8VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a587bde-155a-468e-b46f-abeacd82e7a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A8VF-10A (Blood Derived Normal), aliquot TCGA-QQ-A8VF-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca7abd3e-e510-4ede-b40c-1ba4e2e09718

The open-access MAF lists 876 somatic variants for this specimen: 648 protein-altering or splice-affecting, 213 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 496, Silent 213, Frame Shift Del 92, Nonsense Mutation 24, Frame Shift Ins 23, Splice Site 8, Intron 7, Splice Region 3, RNA 3, 3'UTR 3, In Frame Del 2, 3'Flank 1.

Variants (750 of 876; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 57/71 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.1813del p.I605Yfs*9 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs80359306; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2D | c.15641G>A p.R5214H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFSD8 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749704755, CM091912, COSV56550601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 84/102 reads (82%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NDUFV1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs150966634, CM087532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 19/31 reads (61%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.3598C>T p.R1200* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as rs750586158, COSV54759000; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1024del p.T342Lfs*7 | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | catalogued as rs587778844, CM144108, COSV99927802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SYNGAP1 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1060503384, COSV99538844; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC6 | c.2836del p.L946Sfs*23 | Frame Shift Del (DEL) | VAF 39/76 reads (51%) | catalogued as CM034642; called by mutect2, pindel, varscan2
- ABCF1 | c.1369C>T p.R457C (on ENST00000326195 / NM_001025091.2; = p.R419C on NM_001090.3) | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772178279, COSV100400987; called by muse, mutect2, varscan2
- ACAN | c.6353A>G p.E2118G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs749177064, COSV100718964; called by muse, mutect2
- ACO2 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.078); catalogued as rs142767544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACP3 | c.1042A>C p.S348R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV100313517; called by muse, mutect2, varscan2
- ACSM2B | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373308064, COSV100313364; called by muse, mutect2, varscan2
- ACTL9 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as COSV100185497; called by muse, mutect2, varscan2
- ACTN4 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs561181666, COSV99400624; called by muse, mutect2, varscan2
- ACTR5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs749402313, COSV99710124; called by muse, mutect2, varscan2
- ADAM18 | c.998C>G p.T333S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV99695984; called by muse, mutect2, varscan2
- ADAM30 | c.1946dup p.N649Kfs*14 | Frame Shift Ins (INS) | VAF 19/59 reads (32%) | catalogued as rs752963541; called by mutect2, pindel, varscan2
- ADAMTS17 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs766826340, COSV99171442; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2659G>A p.V887I | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs969369703; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.225); catalogued as rs371922733; called by muse, mutect2, varscan2
- ADGRG3 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100342594; called by muse, mutect2, varscan2
- AGO1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs761121371, COSV100940896; called by muse, mutect2, varscan2
- AGTR1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767462753, COSV100836971; called by muse, varscan2
- AGXT | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs138582006; called by muse, varscan2
- AKAP4 | c.1648A>G p.K550E | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV100654336; called by muse, mutect2, varscan2
- ALG3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749910952, COSV99891596; called by muse, mutect2, varscan2
- ALPK1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs772239630, COSV51593508; called by muse, mutect2, varscan2
- AMPD3 | c.1276C>T p.R426W (on ENST00000396553 / NM_001025389.2; = p.R435W on NM_000480.3) | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs143114453; called by muse, mutect2, varscan2
- ANKRD11 | c.7318G>A p.E2440K | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1008926959, COSV99970292; called by muse, mutect2, varscan2
- ANKRD52 | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776466027, COSV99921542; called by muse, mutect2, varscan2
- AP2M1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53048467; called by muse, mutect2, varscan2
- AP3D1 | c.2936C>T p.P979L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201197577; called by muse, mutect2, varscan2
- APEX1 | c.104_105del p.K35Rfs*11 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as rs764279183; called by mutect2, pindel, varscan2
- API5 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs770680039, COSV66632804, COSV66634384; called by muse, mutect2, varscan2
- APPBP2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.959); catalogued as rs1240854167, COSV99319821; called by muse, mutect2, varscan2
- APPL2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315043; called by muse, mutect2, varscan2
- AQP12A | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs775028865, COSV61837886; called by muse, mutect2, varscan2
- AQP12B | c.337G>A p.A113T (on ENST00000621682; = p.A125T on NM_001102467.2) | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1374452728, COSV68183864; called by muse, mutect2
- ARFGEF1 | c.4033C>T p.R1345* | Nonsense Mutation (SNP) | VAF 32/52 reads (62%) | catalogued as rs146133956, COSV51605657; called by muse, mutect2, varscan2
- ARHGAP26 | c.2416A>G p.I806V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.935); catalogued as rs1193453853, COSV99191297; called by muse, mutect2, varscan2
- ARHGEF15 | c.1366dup p.R456Pfs*2 | Frame Shift Ins (INS) | VAF 13/23 reads (57%) | catalogued as rs1567676744; called by mutect2, pindel, varscan2
- ARID3A | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs749030700, COSV55047191; called by muse, mutect2, varscan2
- ARL8B | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99848781; called by muse, mutect2, varscan2
- ARVCF | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs775972411, COSV99599141; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 48/60 reads (80%) | catalogued as rs761154268; called by mutect2, varscan2
- ATP10A | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs750431834, COSV63520534; called by muse, mutect2, varscan2
- ATP4A | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs371996937; called by muse, mutect2, varscan2
- ATP6V1B1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576236297, COSV99314415; called by muse, mutect2, varscan2
- ATP8B2 | c.1013G>A p.R338H (on ENST00000672630; = p.R305H on NM_001005855.2) | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1353271203, COSV59245873; called by muse, mutect2, varscan2
- ATRN | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99497682; called by muse, mutect2, varscan2
- AXIN1 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 91/109 reads (83%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs769767245, COSV51989449; called by muse, mutect2, varscan2
- B4GALT3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs367870203, COSV60527194; called by muse, mutect2, varscan2
- BAHCC1 | c.5462C>T p.T1821M | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs782463831, COSV57033577; called by muse, mutect2, varscan2
- BAZ2B | c.5645G>A p.R1882Q | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as rs200039167; called by muse, mutect2, varscan2
- BCL2L1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1422601444, COSV100304807; called by muse, mutect2, varscan2
- BRINP1 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs145920249; called by muse, mutect2, varscan2
- BRWD1 | c.4297C>T p.R1433* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as rs752494269, COSV60892572; called by muse, mutect2, varscan2
- BTF3L4 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV100511189; called by muse, mutect2, varscan2
- CACNA1H | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 67/79 reads (85%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1042036647, COSV62005726; called by muse, mutect2, varscan2
- CADM4 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55929099; called by muse, mutect2, varscan2
- CALD1 | c.1585del p.Q529Rfs*76 (on ENST00000361675 / NM_033138.4; = p.Q274Rfs*76 on NM_004342.7) | Frame Shift Del (DEL) | VAF 53/180 reads (29%) | catalogued as rs1554474721; called by mutect2, pindel, varscan2
- CAPG | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs774144382, COSV99809552; called by muse, mutect2, varscan2
- CAPZA1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99583387; called by muse, mutect2, varscan2
- CARD16 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100995112; called by muse, mutect2, varscan2
- CARD6 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.611); catalogued as COSV99621142; called by muse, mutect2
- CASP10 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs748398291, COSV99629256; called by muse, mutect2, varscan2
- CCDC134 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs753645777, COSV55387650; called by muse, mutect2, varscan2
- CCDC17 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs746935513, COSV100601957; called by muse, mutect2, varscan2
- CCDC88C | c.4273C>T p.R1425C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778992254, COSV58660622; called by muse, mutect2, varscan2
- CCDC93 | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 39/46 reads (85%) | catalogued as COSV100099299; called by muse, mutect2, varscan2
- CCN1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs780507440, COSV101486140; called by muse, mutect2, varscan2
- CCR6 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV59475448; called by muse, mutect2, varscan2
- CCT5 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs978444316, COSV99725527; called by muse, mutect2, varscan2
- CCT5 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs368338119; called by muse, mutect2, varscan2
- CD180 | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99842331; called by muse, mutect2, varscan2
- CDC42EP1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs779661388, COSV99312620; called by muse, mutect2, varscan2
- CDH10 | c.1118T>A p.I373N | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052679; called by muse, mutect2, varscan2
- CDH15 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs890942238, COSV99227894, COSV99228724; called by muse, mutect2, varscan2
- CDK20 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs777935532, COSV57482534; called by muse, mutect2, varscan2
- CELF3 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs762261971, COSV99310552; called by muse, mutect2, varscan2
- CELF3 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs966059814, COSV51881765; called by muse, mutect2, varscan2
- CEP162 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100003189; called by muse, mutect2, varscan2
- CEP192 | c.2099G>T p.R700I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs544417355, COSV100381870; called by muse, varscan2
- CETN3 | c.189dup p.A64Sfs*2 | Frame Shift Ins (INS) | VAF 86/190 reads (45%) | catalogued as rs763570929; called by mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 59/85 reads (69%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP54 | c.5149A>G p.I1717V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as COSV100733291; called by muse, mutect2, varscan2
- CFAP74 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs777575611, COSV54565810; called by muse, mutect2, varscan2
- CGN | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376782764; called by muse, mutect2, varscan2
- CHERP | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199553205, COSV99550409; called by muse, mutect2, varscan2
- CHMP2A | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV53396511; called by muse, mutect2, varscan2
- CILP2 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs145521051; called by muse, mutect2, varscan2
- CKMT2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as rs139586793; called by muse, mutect2, varscan2
- CLASP2 | c.3118C>T p.R1040C (on ENST00000359576; = p.R1039C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/76 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs764290497, COSV100224103, COSV56278019; called by muse, mutect2, varscan2
- CLASRP | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.169); catalogued as rs1252230397, COSV99674065; called by muse, varscan2
- CLCN1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs146469288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN4 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 49/56 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs750952479, COSV66467119; called by muse, mutect2, varscan2
- CLDN16 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs968906940, CM014949, CM034402, COSV53228456, COSV53228640; called by muse, mutect2, varscan2
- CLDN8 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV54526793; called by muse, mutect2, varscan2
- CLEC18B | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1347648416, COSV100376088; called by muse, mutect2, varscan2
- CLINT1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767848630, COSV99754525; called by muse, mutect2, varscan2
- CLVS1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1465656591, COSV57977822; called by muse, mutect2, varscan2
- CNOT3 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV99652242; called by muse, mutect2, varscan2
- CNTN2 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772630695, COSV100084535; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 34/41 reads (83%) | catalogued as rs374805044; called by mutect2, varscan2
- COL28A1 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101258864; called by muse, mutect2
- COL3A1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779625, CM119018, COSV100483591; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COL5A3 | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs375027130; called by muse, mutect2, varscan2
- COL8A2 | c.668del p.G223Vfs*14 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as COSV57443421; called by mutect2, varscan2
- COQ6 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV99474119; called by muse, mutect2, varscan2
- CPNE6 | c.1390A>G p.M464V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs1436450336, COSV99393650; called by muse, mutect2, varscan2
- CPT1A | c.1094G>T p.R365M | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99681500; called by muse, mutect2, varscan2
- CRYBG1 | c.6161C>T p.T2054M | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759315548, COSV100954597; called by muse, mutect2, varscan2
- CSF2RA | c.1043G>T p.R348M | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100817902; called by muse, mutect2
- CSMD1 | c.3740C>T p.P1247L (on ENST00000520002; = p.P1246L on NM_033225.6) | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs775093026, COSV100152372; called by muse, mutect2, varscan2
- CSN1S1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs376905625; called by muse, mutect2, varscan2
- CTDP1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs773660470, COSV50008091; called by muse, mutect2, varscan2
- CTLA4 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55593647; called by muse, mutect2, varscan2
- CTSG | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99361661; called by muse, mutect2, varscan2
- CTSH | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1158014802, COSV54984742; called by muse, mutect2, varscan2
- CUX1 | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.931); catalogued as rs1554537988, COSV99472672; called by muse, mutect2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 45/97 reads (46%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP3A7 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748017013, COSV60480698, COSV60482109; called by muse, mutect2, varscan2
- CYP3A7 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs777420600, COSV100312821; called by muse, mutect2, varscan2
- CYP4F2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV99686244; called by muse, mutect2, varscan2
- DAB2IP | c.3352G>A p.A1118T (on ENST00000408936; = p.A1090T on NM_032552.3) | Missense Mutation (SNP) | VAF 89/99 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs1564237169, COSV52255051; called by muse, mutect2, varscan2
- DBF4 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as rs144858770; called by muse, mutect2, varscan2
- DCHS1 | c.4966G>A p.V1656I | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs978531303, COSV100202454; called by muse, mutect2, varscan2
- DDX23 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100339945; called by muse, mutect2, varscan2
- DDX42 | c.2090C>T p.T697M | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1343472038, COSV100835029; called by muse, mutect2, varscan2
- DDX55 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs777882464, COSV99434750; called by muse, mutect2, varscan2
- DEAF1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.68); PolyPhen benign (0.1); catalogued as COSV100102278; called by muse, mutect2, varscan2
- DENND3 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs148369529; called by muse, varscan2
- DIP2A | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs200938637, COSV100596230; called by muse, mutect2, varscan2
- DIPK2B | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); catalogued as COSV100933462; called by muse, mutect2, varscan2
- DISP3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99609677; called by muse, mutect2
- DLGAP2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs375426065; called by muse, mutect2, varscan2
- DMD | c.7384C>T p.P2462S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100628696; called by muse, mutect2, varscan2
- DMXL1 | c.4105C>T p.R1369C | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs986354834, COSV100224655; called by muse, mutect2, varscan2
- DNAH10 | c.5720C>A p.A1907E (on ENST00000409039; = p.A1846E on NM_207437.3) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101292499; called by muse, mutect2, varscan2
- DNAH10 | c.9128C>T p.P3043L (on ENST00000409039; = p.P2982L on NM_207437.3) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs368623243; called by muse, mutect2, varscan2
- DNAH8 | c.10325G>T p.G3442V | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV100546733; called by muse, mutect2, varscan2
- DNAJB6 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1377762197, COSV100055874; called by muse, mutect2, varscan2
- DNM1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs933803259, COSV100360242; called by muse, mutect2, varscan2
- DOC2A | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 24/31 reads (77%) | catalogued as COSV100451362; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs748134881; called by mutect2, varscan2
- DOP1B | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs766473651, COSV67692310; called by muse, mutect2, varscan2
- DPY19L1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1448866263, COSV100204892; called by muse, mutect2, varscan2
- DPYSL3 | c.969C>T p.S323= | Splice Region (SNP) | VAF 7/52 reads (13%) | catalogued as rs751007269, COSV100575384, COSV58327214; called by mutect2, varscan2
- DTX4 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs771762579, COSV99915862; called by muse, mutect2, varscan2
- DUSP18 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV100588849; called by muse, mutect2, varscan2
- DUSP8 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1244646421, COSV100524483; called by muse, mutect2, varscan2
- DYNC1H1 | c.6148G>A p.A2050T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99080988; called by muse, mutect2, varscan2
- EAF2 | c.334dup p.T112Nfs*4 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | catalogued as rs746509911; called by mutect2, varscan2
- EBF1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV100566342; called by muse, mutect2, varscan2
- ECHDC3 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 111/131 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs747805459, COSV64867208; called by muse, mutect2, varscan2
- ECI1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 44/56 reads (79%) | catalogued as COSV100066955; called by muse, mutect2, varscan2
- EGFR | c.2950del p.X984_splice | Splice Site (DEL) | VAF 34/88 reads (39%) | catalogued as rs1562805519, COSV51766463; called by mutect2, pindel, varscan2
- EGLN2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973122075, COSV58281122; called by muse, mutect2, varscan2
- EIF3D | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs749458696, COSV53405215; called by muse, mutect2, varscan2
- EIF4E1B | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs779126438, COSV53780811; called by muse, mutect2, varscan2
- EMC8 | c.308+1G>A p.X103_splice | Splice Site (SNP) | VAF 46/48 reads (96%) | catalogued as COSV99495777; called by muse, mutect2, varscan2
- EPB41L4A | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs779756431, COSV54865238; called by muse, mutect2, varscan2
- ESPL1 | c.3407T>C p.I1136T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs777519085, COSV99229633; called by muse, mutect2, varscan2
- ETV5 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as COSV100112512; called by muse, mutect2
- F11R | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV99231128; called by muse, mutect2, varscan2
- F12 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99499881; called by muse, mutect2, varscan2
- FAM160A2 | c.1855C>T p.R619W (on ENST00000449352 / NM_001098794.2; = p.R633W on NM_032127.4) | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780305032, COSV99792400; called by muse, varscan2
- FAM3D | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs767389905, COSV100716969; called by muse, mutect2, varscan2
- FAM53B | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs765399560, COSV99785015; called by muse, mutect2, varscan2
- FAM71B | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs753781161, COSV57227593; called by muse, mutect2, varscan2
- FASTKD3 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs577450607, COSV99242648; called by muse, mutect2, varscan2
- FASTKD3 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1483812326, COSV99241979; called by muse, mutect2, varscan2
- FBLN1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs542978755, COSV99411207; called by muse, varscan2
- FBLN1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs755416957, COSV53048236; called by muse, varscan2
- FBN3 | c.8252G>A p.R2751H | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764446097, COSV99495230; called by muse, mutect2, varscan2
- FBXL2 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1231832103, COSV52137130; called by muse, mutect2, varscan2
- FBXW9 | c.1204C>T p.R402W (on ENST00000587955; = p.R382W on NM_032301.3) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1047756662, COSV100982056; called by muse, mutect2, varscan2
- FCGBP | c.10387G>A p.G3463S | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as rs776380141; called by muse, mutect2, varscan2
- FCGBP | c.2839G>A p.V947I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as rs907330541; called by muse, mutect2, varscan2
- FCHSD1 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs769500524, COSV99781453; called by muse, mutect2, varscan2
- FHDC1 | c.3102C>A p.S1034R | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99471586; called by muse, mutect2, varscan2
- FHDC1 | c.3278G>A p.R1093Q | Missense Mutation (SNP) | VAF 99/116 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs761362205, COSV52600915; called by muse, mutect2, varscan2
- FHOD3 | c.2471G>T p.R824M (on ENST00000359247 / NM_001281739.3; = p.R841M on NM_025135.5) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as rs770364602, COSV99942299; called by muse, mutect2, varscan2
- FICD | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as rs758354977, COSV57209595; called by muse, mutect2, varscan2
- FLII | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs755561718, COSV100493791; called by muse, mutect2, varscan2
- FLOT2 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457026667, COSV101204794; called by mutect2, varscan2
- FMNL3 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1420812239, COSV99526824; called by muse, mutect2, varscan2
- FNDC1 | c.2920C>T p.R974C | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1371359713, COSV51946447; called by muse, mutect2, varscan2
- FOXA1 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99163662; called by muse, varscan2
- FSCN2 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1348139370, COSV100603319; called by muse, mutect2, varscan2
- FURIN | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184764; called by muse, mutect2, varscan2
- FURIN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184765; called by muse, mutect2, varscan2
- FZD9 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs776032343, COSV59994723; called by muse, mutect2, varscan2
- GABBR2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as rs1449813941, COSV99411110; called by muse, mutect2, varscan2
- GABRB2 | c.1257G>T p.E419D (on ENST00000274547; = p.E381D on NM_000813.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as COSV99196431; called by muse, mutect2, varscan2
- GABRR1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 67/79 reads (85%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); catalogued as rs775793721, COSV65618895; called by muse, mutect2, varscan2
- GAD2 | c.1494G>T p.K498N | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV99393838; called by muse, mutect2, varscan2
- GALNT17 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs547461426, COSV100355488; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 47/78 reads (60%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GBP4 | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 33/45 reads (73%) | catalogued as COSV100864399; called by muse, mutect2, varscan2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs761897305; called by mutect2, varscan2
- GGN | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs748092486, COSV99287403; called by muse, mutect2, varscan2
- GHITM | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1373394931, COSV100930123; called by muse, mutect2, varscan2
- GNB5 | c.391G>A p.V131M (on ENST00000261837 / NM_016194.4; = p.V89M on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1253307264, COSV99953578; called by muse, mutect2, varscan2
- GOLGA3 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as rs552029921, COSV99212401; called by muse, mutect2, varscan2
- GOLGA5 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774532511, COSV50832463; called by muse, mutect2, varscan2
- GPR32 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs755214712, COSV99567176; called by muse, varscan2
- GPR37 | c.1335G>A p.W445* | Nonsense Mutation (SNP) | VAF 52/206 reads (25%) | catalogued as COSV100391093; called by muse, mutect2, varscan2
- GPR45 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs903481209, COSV51525098; called by muse, mutect2, varscan2
- GPRIN3 | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs753028741, COSV60884342, COSV60885562; called by muse, mutect2, varscan2
- GRAMD1A | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100526357; called by muse, mutect2, varscan2
- GRAMD4 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1174840060, COSV100730601; called by muse, mutect2, varscan2
- GRIN3A | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs941485044, COSV62450158; called by muse, mutect2, varscan2
- GRM6 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs369555190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUSB | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs753883162, COSV100512726; called by muse, mutect2, varscan2
- GZMB | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs142224147, COSV53541014; called by muse, mutect2, varscan2
- H1-8 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT tolerated (0.7); PolyPhen benign (0.086); catalogued as rs374505410, COSV60974378; called by muse, mutect2, varscan2
- HDGFL2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs918976256, COSV100012396; called by muse, mutect2, varscan2
- HDGFL2 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs764649877, COSV100012397; called by muse, mutect2, varscan2
- HEATR6 | c.2819A>G p.Q940R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs370637299; called by muse, mutect2, varscan2
- HECTD4 | c.10345G>A p.G3449R | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs537066715, COSV101107828; called by muse, mutect2, varscan2
- HERC1 | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101496806; called by muse, mutect2, varscan2
- HERC1 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1267494510, COSV71247085, COSV71249758; called by muse, mutect2, varscan2
- HIP1R | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765243628, COSV53446029; called by muse, mutect2, varscan2
- HIRA | c.2424del p.E810Kfs*13 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as COSV99600838; called by mutect2, pindel, varscan2
- HNF1B | c.1006del p.H336Tfs*40 | Frame Shift Del (DEL) | VAF 40/60 reads (67%) | catalogued as CM067046; called by mutect2, pindel, varscan2
- HOOK1 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs186136447; called by muse, mutect2, varscan2
- HOXD4 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs374609255; called by muse, mutect2, varscan2
- IGF1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs1316717107, COSV61031712; called by muse, mutect2, varscan2
- IGHG4 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778619198; called by muse, mutect2, varscan2
- IL34 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs201784459, COSV99851964; called by muse, mutect2, varscan2
- INTU | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs200105767, COSV58876333; called by muse, mutect2, varscan2
- IP6K1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1160659107, COSV100390057; called by muse, mutect2, varscan2
- IRAK2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 65/69 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs769170523, COSV99844035; called by muse, mutect2, varscan2
- IRF8 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs372863612, COSV51900668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB3 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs763475276, COSV71383381; called by muse, mutect2, varscan2
- ITGB4 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 67/86 reads (78%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs557212429, COSV99564563; called by muse, mutect2, varscan2
- ITGB7 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs766953169, COSV99914229; called by muse, mutect2, varscan2
- ITIH4 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs754898084, COSV99818791; called by muse, mutect2, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs1555369773; called by mutect2, pindel, varscan2
- JMJD7-PLA2G4B | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148623870; called by muse, mutect2, varscan2
- JPH1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs142292285, COSV60609580; called by muse, mutect2
- KALRN | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs899670932, COSV99566630; called by muse, mutect2, varscan2
- KCNB2 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.306); catalogued as rs758297898, COSV73050312; called by muse, mutect2, varscan2
- KCNK5 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs886586058, COSV100851869; called by muse, mutect2, varscan2
- KCTD2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59369508; called by muse, mutect2, varscan2
- KCTD6 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs779042947, COSV100250262; called by muse, mutect2, varscan2
- KDM6B | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99642085; called by muse, mutect2, varscan2
- KEAP1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as rs535659039, COSV99408145; called by muse, mutect2, varscan2
- KEL | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs747754194, COSV100787249; called by muse, mutect2, varscan2
- KHDC3L | c.168C>T p.F56= | Splice Region (SNP) | VAF 18/22 reads (82%) | catalogued as COSV100951146; called by muse, mutect2, varscan2
- KIAA1549 | c.5440G>A p.G1814R | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747209602, COSV54316778, COSV99651669; called by muse, mutect2, varscan2
- KIAA1755 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs201894627, COSV99642530; called by muse, mutect2, varscan2
- KIF3B | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1381386084, COSV100996491; called by muse, mutect2, varscan2
- KIF7 | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747632760, COSV51544087; called by muse, mutect2, varscan2
- KIR3DL1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100428789; called by muse, mutect2, varscan2
- KLHDC7A | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs773099714, COSV68769590; called by muse, mutect2, varscan2
- KLHDC7A | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 66/73 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs778130409, COSV68770114; called by muse, mutect2, varscan2
- KLHL40 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767572121, COSV99825671, COSV99825706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.12466del p.Q4156Nfs*5 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as COSV56431444; called by mutect2, pindel, varscan2
- KNDC1 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1462152347, COSV100465949; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 42/94 reads (45%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRR1 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as rs901056089, COSV99875698, COSV99875835; called by muse, mutect2, varscan2
- KRT73 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756805566, COSV59838910; called by muse, mutect2, varscan2
- KRT83 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs201760909, COSV99531831; called by muse, mutect2
- L3MBTL1 | c.427C>T p.R143W (on ENST00000418998 / NM_001377303.1; = p.R53W on NM_015478.7) | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1161853602, COSV64234591; called by muse, mutect2, varscan2
- LAMA3 | c.1996T>C p.C666R | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557478; called by muse, mutect2, varscan2
- LAMA5 | c.7474G>A p.A2492T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373181217; called by muse, mutect2, varscan2
- LAMA5 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477333118, COSV99441652; called by muse, mutect2, varscan2
- LASP1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58806245; called by muse, mutect2, varscan2
- LHX2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 138/155 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV101010080; called by muse, mutect2, varscan2
- LIMK1 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782270979, COSV100283380; called by muse, mutect2, varscan2
- LMF2 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs371376101; called by muse, mutect2, varscan2
- LPIN2 | c.2569G>A p.V857M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346809433, COSV99598800; called by muse, mutect2, varscan2
- LRIG2 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100743608; called by muse, mutect2, varscan2
- LRRC14B | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs763290010, COSV52054799; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC59 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV56813728; called by muse, mutect2, varscan2
- LRRFIP1 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753383113, COSV100406222; called by muse, mutect2, varscan2
- LTBP4 | c.889G>A p.E297K (on ENST00000308370 / NM_001042544.1; = p.E260K on NM_003573.2) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1376567591, COSV99199192; called by muse, mutect2, varscan2
- LY75 | c.5053G>A p.G1685R | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs748410848, COSV99716422, COSV99716850; called by muse, mutect2, varscan2
- MACROD1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs760778212, COSV55360644; called by muse, mutect2, varscan2
- MAP1S | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs965878171, COSV60723533; called by muse, mutect2
- MAP2 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99561330; called by muse, mutect2, varscan2
- MAP3K7 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs1185961784, COSV100997518; called by muse, mutect2, varscan2
- MAP3K9 | c.3083C>T p.T1028M (on ENST00000554752 / NM_001284230.1; = p.T1042M on NM_033141.4) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs148083571, COSV67123323; called by muse, mutect2, varscan2
- MAP4K2 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs779211660, COSV99581470; called by muse, mutect2, varscan2
- MAP7 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs767620454, COSV100643982; called by muse, mutect2, varscan2
- MAP9 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772931614, COSV100250856; called by muse, mutect2, varscan2
- MAPK6 | c.1994G>A p.S665N | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99959349; called by muse, mutect2, varscan2
- MAST1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99263515; called by muse, mutect2, varscan2
- MAST1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0.037); catalogued as rs780395283, COSV52255369; called by muse, mutect2, varscan2
- MAST3 | c.3094C>A p.L1032M | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99446091; called by muse, mutect2, varscan2
- MBTPS2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs938412288, COSV100810876, COSV63412128; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MGAT4C | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770702724, COSV59832815, COSV59833353; called by muse, mutect2, varscan2
- MICAL3 | c.5617G>A p.V1873M | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76474025, COSV101490862; called by muse, mutect2, varscan2
- MICAL3 | c.4226A>G p.D1409G | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV101490936; called by muse, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MINPP1 | c.857del p.F286Sfs*22 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | catalogued as rs1435705057; called by mutect2, pindel, varscan2
- MMP2 | c.146T>C p.L49S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99528150; called by muse, mutect2
- MMS22L | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs780279190, COSV99247553; called by muse, mutect2, varscan2
- MNDA | c.164del p.K55Sfs*8 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs750084919, COSV100933258; called by mutect2, pindel, varscan2
- MOV10 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs772742073, COSV100659728; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 40/84 reads (48%) | catalogued as rs756600463; called by mutect2, varscan2
- MROH5 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.852); catalogued as rs747181517, COSV101436094; called by muse, mutect2
- MTERF2 | c.1071dup p.E358Rfs*3 | Frame Shift Ins (INS) | VAF 46/93 reads (49%) | catalogued as rs1220978731; called by mutect2, varscan2
- MTF2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 108/127 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1275420195, COSV100940168; called by muse, mutect2, varscan2
- MTUS2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs372358810, COSV101462273; called by muse, mutect2, varscan2
- MUC16 | c.40471C>T p.R13491W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); catalogued as rs541610415, COSV66689793, COSV66695495; called by muse, mutect2
- MYH15 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99844033; called by muse, mutect2, varscan2
- MYH7B | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs924925102, COSV99483179; called by muse, mutect2, varscan2
- MYO18A | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs747144978, COSV62863875; called by muse, mutect2, varscan2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 32/125 reads (26%) | catalogued as rs748007891; called by mutect2, pindel, varscan2
- MYO18B | c.5581C>A p.L1861M | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV100124675; called by muse, mutect2, varscan2
- MYO18B | c.5851C>T p.R1951C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs377156253; called by muse, mutect2, varscan2
- MYO1G | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99349011; called by muse, mutect2, varscan2
- MYO3B | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572179158, COSV58710490, COSV58711875; called by muse, mutect2, varscan2
- MYO3B | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs551614508, COSV58711757; called by muse, mutect2, varscan2
- NBEA | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371995725; called by muse, mutect2, varscan2
- NCKAP1L | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780225435, COSV53208069; called by muse, mutect2, varscan2
- NCKAP5L | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 38/75 reads (51%) | catalogued as COSV60129767; called by muse, mutect2, varscan2
- NCOA3 | c.3917C>T p.P1306L (on ENST00000371998 / NM_181659.3; = p.P1302L on NM_006534.4) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as rs376614401; called by muse, mutect2, varscan2
- NCOA6 | c.4795_4796del p.V1599Ifs*12 | Frame Shift Del (DEL) | VAF 56/112 reads (50%) | catalogued as rs770872136; called by mutect2, pindel, varscan2
- NCOR2 | c.4687C>T p.R1563W | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1197943035, COSV100657746; called by muse, mutect2, varscan2
- NDNF | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV65634498; called by muse, mutect2, varscan2
- NDUFC2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs772399659, COSV55246351; called by muse, mutect2, varscan2
- NFE2L1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750380583, COSV62583036; called by muse, mutect2, varscan2
- NFE2L1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748372833, COSV62583774; called by muse, mutect2, varscan2
- NIPAL3 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs747947177, COSV99135455; called by muse, mutect2, varscan2
- NKD1 | c.862del p.R288Afs*59 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs772439983; called by mutect2, pindel, varscan2
- NKX2-4 | c.182C>G p.T61S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100698623; called by muse, mutect2, varscan2
- NLK | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 79/100 reads (79%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.885); catalogued as COSV101311313; called by muse, mutect2, varscan2
- NLRP1 | c.663_666del p.E225Nfs*13 | Frame Shift Del (DEL) | VAF 23/29 reads (79%) | catalogued as rs1188925326; called by mutect2, pindel, varscan2
- NNT | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV99239392; called by muse, mutect2, varscan2
- NOL8 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201741030, COSV62635419; called by muse, mutect2, varscan2
- NOP9 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1179196451, COSV99351072; called by muse, mutect2, varscan2
- NOTCH3 | c.6089C>A p.P2030H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99658444; called by muse, mutect2, varscan2
- NPAS1 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV99451439; called by muse, mutect2, varscan2
- NPC1L1 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs868457703, COSV56922246; called by muse, mutect2, varscan2
- NPEPL1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs62639982, COSV100622300; called by muse, mutect2, varscan2
- NR1H2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1568595480, COSV99516196; called by muse, mutect2, varscan2
- NRCAM | c.418C>T p.R140C (on ENST00000379028 / NM_001371124.1; = p.R134C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1043183630, COSV100694655, COSV100695250; called by muse, mutect2, varscan2
- NUAK1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147896976; called by muse, mutect2, varscan2
- NUP107 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99971477; called by muse, mutect2, varscan2
- OCA2 | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs138606284; called by muse, mutect2, varscan2
- OPLAH | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782053576, COSV101470855; called by muse, mutect2, varscan2
- OR10G2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs746330187, COSV101606933; called by muse, mutect2, varscan2
- OR11H4 | c.204del p.M69Cfs*24 | Frame Shift Del (DEL) | VAF 38/91 reads (42%) | catalogued as rs1158642856, COSV59559737; called by mutect2, pindel, varscan2
- OR2A25 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1334786713, COSV101376410, COSV68717647; called by muse, mutect2, varscan2
- OR2T33 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs368660679; called by muse, mutect2
- OR2T8 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs373532215; called by muse, mutect2, varscan2
- OR51E1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760647045, COSV67809478, COSV67810339; called by muse, mutect2, varscan2
- OR9I1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1383005002, COSV100110371; called by muse, mutect2, varscan2
- OXTR | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199856198; called by muse, mutect2, varscan2
- PACS2 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1488845742, COSV100330937; called by muse, mutect2, varscan2
- PAM | c.2819G>A p.R940Q (on ENST00000438793 / NM_001319943.1; = p.R941Q on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.146); catalogued as rs759133083, COSV99173721; called by muse, mutect2, varscan2
- PBRM1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs774655494, COSV56294959, COSV56298403; called by muse, mutect2, varscan2
- PCBP3 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs916264253, COSV68406497; called by muse, mutect2, varscan2
- PCDHA4 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV63543231; called by muse, mutect2, varscan2
- PCDHA4 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as rs77547730, COSV63541918, COSV63542468; called by muse, mutect2, varscan2
- PCDHGB4 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773579820, COSV53992639; called by muse, mutect2, varscan2
- PCDHGB7 | c.1975A>G p.T659A | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV99544222; called by muse, mutect2, varscan2
- PCDHGC4 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as COSV99341187; called by muse, mutect2, varscan2
- PCLO | c.6521C>T p.T2174I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.803); catalogued as COSV100436272; called by muse, mutect2, varscan2
- PDE6A | c.2229G>A p.W743* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99678581; called by muse, mutect2, varscan2
- PDILT | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100199727; called by muse, mutect2, varscan2
- PDZRN4 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs771316958, COSV101284522; called by muse, mutect2, varscan2
- PES1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs545460660, COSV58827920; called by muse, mutect2, varscan2
- PFKFB2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 42/49 reads (86%) | PolyPhen benign (0.009); catalogued as COSV100892039; called by muse, mutect2, varscan2
- PHF21B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1257044699, COSV100503829, COSV57562990; called by muse, mutect2, varscan2
- PI4KA | c.5567G>A p.R1856Q | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159765642, COSV99748007; called by muse, mutect2, varscan2
- PI4KA | c.2108G>T p.R703M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99748012; called by muse, mutect2, varscan2
- PIGQ | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.474); catalogued as rs774945335, COSV50314553; called by muse, varscan2
- PIKFYVE | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1459743898, COSV100011259; called by muse, mutect2, varscan2
- PIWIL2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs772112294, COSV100769106; called by muse, mutect2, varscan2
- PKD1 | c.10984C>T p.R3662C (on ENST00000262304 / NM_001009944.3; = p.R3661C on NM_000296.4) | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770600083, CD022740, COSV99238599, COSV99238815; called by muse, mutect2, varscan2
- PKDREJ | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs117756687, COSV99479410; called by muse, mutect2, varscan2
- PLAUR | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99655357; called by muse, mutect2, varscan2
- PLCG1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201158224, COSV99719153; called by muse, mutect2, varscan2
- PLEKHF2 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100193594; called by muse, mutect2, varscan2
- PLEKHO2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772570561, COSV100060901; called by muse, mutect2, varscan2
- PLPPR2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV99264674; called by muse, mutect2, varscan2
- PNKP | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs1041964950, COSV100465586; called by muse, mutect2, varscan2
- PNN | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV53768154; called by muse, mutect2, varscan2
- POC5 | c.865C>T p.R289C (on ENST00000428202 / NM_001099271.2; = p.R264C on NM_152408.2) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1561467862, COSV100700705; called by muse, varscan2
- PODNL1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.363); catalogued as rs941227990, COSV99583005; called by muse, mutect2, varscan2
- POGK | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs762404380, COSV63311675; called by muse, mutect2, varscan2
- POU5F2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1171257915, COSV101232905; called by muse, mutect2, varscan2
- PPFIA1 | c.3493C>T p.R1165W | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373954004; called by muse, mutect2, varscan2
- PPFIA3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61955461; called by muse, mutect2, varscan2
- PPFIBP1 | c.1579C>T p.R527W (on ENST00000318304 / NM_177444.3; = p.R510W on NM_003622.4) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs778133603, COSV57295735, COSV99945277; called by muse, mutect2, varscan2
- PPP1R26 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs148477106; called by muse, mutect2, varscan2
- PRDM10 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100456802; called by muse, mutect2, varscan2
- PRDM15 | c.3394del p.Q1132Sfs*16 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | catalogued as rs1568866450; called by mutect2, pindel, varscan2
- PRKCE | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs748930507, COSV100079087; called by muse, mutect2, varscan2
- PRKCE | c.1904T>A p.V635D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100079091; called by muse, mutect2, varscan2
- PSD2 | c.2140C>A p.L714I | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV99217437; called by muse, mutect2, varscan2
- PSG4 | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV54936314; called by muse, mutect2, varscan2
- PSMC1 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1249837053, COSV99728513; called by muse, mutect2, varscan2
- PSME1 | c.135+2T>C p.X45_splice | Splice Site (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99246444; called by muse, mutect2, varscan2
- PTPN12 | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99950610; called by muse, mutect2, varscan2
- PUS7 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346711839, COSV100708614; called by muse, mutect2, varscan2
- PXDNL | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100681371; called by muse, varscan2
- PZP | c.3074A>G p.K1025R | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99738990; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs755727862; called by mutect2, varscan2
- RAC1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.415); catalogued as COSV100641015, COSV61823555; called by muse, mutect2
- RANBP3 | c.1458G>T p.K486N (on ENST00000340578 / NM_007322.3; = p.K481N on NM_003624.3) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99222458; called by muse, mutect2, varscan2
- RAP1GAP | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765382564, COSV51578685, COSV99265704; called by muse, mutect2, varscan2
- RASGRP1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172199; called by muse, mutect2, varscan2
- RBFOX1 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as rs781081302, COSV60947493; called by muse, mutect2, varscan2
- RBFOX2 | c.392T>C p.L131P (on ENST00000438146 / NM_001349995.2; = p.L61P on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99455701; called by muse, mutect2, varscan2
- RBM25 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99998950; called by muse, mutect2, varscan2
- RBM28 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV99775863; called by muse, mutect2, varscan2
- RBMX2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV59728375; called by muse, mutect2
- RDX | c.1412dup p.P472Sfs*16 | Frame Shift Ins (INS) | VAF 38/54 reads (70%) | catalogued as rs780998172; called by mutect2, varscan2
- RECQL4 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs534507419, COSV52879816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGL3 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.852); catalogued as rs1251633773, COSV100710609; called by muse, mutect2, varscan2
- RGMA | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.891); catalogued as rs776144797, COSV61236875; called by muse, mutect2, varscan2
- RHPN2 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs199630139; called by muse, mutect2, varscan2
- ROBO1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.953); catalogued as COSV101518019; called by muse, mutect2, varscan2
- RPGRIP1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374913550; called by muse, mutect2, varscan2
- RREB1 | c.4468G>A p.D1490N | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs776759831, COSV100619728; called by muse, mutect2, varscan2
- RSPH3 | c.1027C>T p.R343W (on ENST00000252655; = p.R201W on NM_031924.8) | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs142857859; called by muse, mutect2, varscan2
- RTL1 | c.2890G>A p.V964I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.18); catalogued as rs778114790, COSV66016779; called by muse, mutect2, varscan2
- RTN2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.528); catalogued as rs776780195, COSV55593396; called by muse, mutect2, varscan2
- RYR1 | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376526576, CM137492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.4598C>T p.A1533V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs368925275, COSV66805612; called by muse, mutect2, varscan2
- SAMD1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1246451816, COSV99513924; called by muse, mutect2, varscan2
- SASH1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.439); catalogued as COSV100821383; called by muse, mutect2, varscan2
- SBF1 | c.4973G>A p.R1658H | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550773035, COSV100817967; called by muse, mutect2, varscan2
- SCAND1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1009379814, COSV100018982; called by muse, mutect2, varscan2
- SCN5A | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749651069, COSV61118544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDF2L1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770913117, COSV99963664; called by muse, mutect2, varscan2
- SDHA | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53769422, COSV53770412; called by muse, mutect2
- SEC14L5 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99229281; called by muse, mutect2, varscan2
- SEC24B | c.3347T>C p.M1116T | Missense Mutation (SNP) | VAF 63/76 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99494113; called by muse, mutect2, varscan2
- SEC31A | c.3319del p.I1107Lfs*13 (on ENST00000355196 / NM_001318120.1; = p.I1068Lfs*13 on NM_016211.4) | Frame Shift Del (DEL) | VAF 36/48 reads (75%) | catalogued as rs764353087, COSV52352147; called by mutect2, varscan2
- SEMA4D | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780068652, COSV100358677; called by muse, mutect2, varscan2
- SEMA6B | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV100015058; called by muse, mutect2, varscan2
- SEMA6D | c.2989C>T p.R997C (on ENST00000316364 / NM_153618.2; = p.R935C on NM_020858.2) | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs763608914, COSV60373241; called by muse, mutect2, varscan2
- SENP1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1239495661, COSV50301479; called by muse, mutect2, varscan2
- SEZ6 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs548180123, COSV100253414; called by muse, mutect2, varscan2
- SFSWAP | c.1184C>G p.T395S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99906311; called by muse, mutect2, varscan2
- SFXN1 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as rs760020898, COSV100369410; called by muse, mutect2, varscan2
- SHANK2 | c.4169G>A p.R1390H | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs781838189, COSV99571443; called by muse, mutect2, varscan2
- SIK3 | c.1993C>T p.R665C (on ENST00000445177 / NM_001366686.2; = p.R623C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754313423, COSV52619979; called by muse, mutect2, varscan2
- SLC12A1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747229048, CM981819, COSV100372506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC13A5 | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99546114; called by muse, mutect2, varscan2
- SLC1A5 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376590378, COSV69467326; called by muse, mutect2, varscan2
- SLC22A25 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs762029744, COSV100123860; called by muse, mutect2, varscan2
- SLC25A13 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs199744651, COSV55706361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A47 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1000904537, COSV100836567; called by muse, mutect2, varscan2
- SLC25A48 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs758384952, COSV99192133; called by muse, mutect2, varscan2
- SLC25A6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as rs200654415, COSV101195486; called by muse, mutect2, varscan2
- SLC27A5 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99564562; called by muse, mutect2
- SLC28A1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs375692167; called by muse, mutect2, varscan2
- SLC34A1 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs373490491; called by muse, mutect2, varscan2
- SLC35E3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1419729625, COSV99971973; called by muse, mutect2, varscan2
- SLC9A3 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as rs142560041; called by muse, mutect2, varscan2
- SLC9A4 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs780812176, COSV54834743; called by muse, mutect2, varscan2
- SLCO4A1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs369212474; called by muse, mutect2, varscan2
- SLTM | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99989360; called by muse, mutect2, varscan2
- SMPD3 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99545946; called by muse, mutect2, varscan2
- SND1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61235157; called by muse, mutect2, varscan2
- SNRNP70 | c.46dup p.R16Pfs*2 | Frame Shift Ins (INS) | VAF 34/318 reads (11%) | catalogued as rs1183371144; called by mutect2, pindel
- SNX25 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172291640, COSV99253337; called by muse, mutect2, varscan2
- SOAT2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs757094894, COSV100037247; called by muse, mutect2, varscan2
- SP3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs753208366, COSV59466046; called by muse, mutect2, varscan2
- SPACA3 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); catalogued as rs776577098, COSV52192854; called by muse, mutect2, varscan2
- SPINK1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs536203389, COSV57024897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTAN1 | c.4603C>T p.R1535C | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); catalogued as rs780733897, COSV100823908; called by muse, mutect2, varscan2
- SPTBN4 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs545119009, COSV58943011; called by muse, mutect2, varscan2
- SPTBN4 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100150257; called by muse, mutect2, varscan2
- SPTBN5 | c.5596C>T p.R1866W | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs200576078; called by muse, mutect2, varscan2
- SSH1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs199897989, COSV58455330; called by muse, mutect2, varscan2
- SSH3 | c.370del p.R124Gfs*7 | Frame Shift Del (DEL) | VAF 24/34 reads (71%) | catalogued as COSV57384737; called by mutect2, varscan2
- ST6GALNAC3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 63/76 reads (83%) | PolyPhen possibly damaging (0.692); catalogued as rs369940675; called by muse, mutect2, varscan2
- STAG2 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 26/29 reads (90%) | catalogued as COSV54351672; called by muse, mutect2, varscan2
- STAU1 | c.616C>T p.R206W (on ENST00000371856 / NM_001319135.1; = p.R125W on NM_004602.3) | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs143151409; called by muse, mutect2, varscan2
- STC1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143373578; called by muse, mutect2, varscan2
- STXBP3 | c.258+2T>C p.X86_splice | Splice Site (SNP) | VAF 85/110 reads (77%) | catalogued as COSV100894051; called by muse, mutect2, varscan2
- SYMPK | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780926621, COSV99841988; called by muse, mutect2, varscan2
- TAB1 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs759175996, COSV99336222; called by muse, mutect2, varscan2
- TACC3 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs138731272; called by muse, mutect2, varscan2
- TAF6 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs745911313, COSV100612835; called by muse, mutect2, varscan2
- TAOK3 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1277510978, COSV101183685; called by muse, mutect2, varscan2
- TBCCD1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs750391893, COSV58663419; called by muse, mutect2, varscan2
- TBL1Y | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60733897; called by muse, mutect2, varscan2
- TBX22 | c.633+1G>A p.X211_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as CS013116, COSV100960911; called by muse, mutect2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs763438715; called by mutect2, varscan2
- TECTA | c.3284G>A p.R1095H | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs771933470, COSV50716628, COSV99881136; called by muse, mutect2, varscan2
- TENM1 | c.5854C>T p.R1952* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV64431988; called by muse, mutect2, varscan2
- TEP1 | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs779605418, COSV52987617; called by muse, mutect2, varscan2
- TEP1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99403021; called by muse, mutect2, varscan2
- TESK1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs750389597, COSV52411902; called by muse, mutect2, varscan2
- TFPT | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs142515991; called by muse, mutect2, varscan2
- THAP3 | c.641G>A p.R214Q (on ENST00000054650 / NM_001195753.1; = p.R213Q on NM_001195752.1) | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371978899; called by muse, mutect2, varscan2
- TICRR | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1307750974, COSV99179135; called by muse, mutect2, varscan2
- TJP1 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.167); catalogued as rs541526165, COSV100633029; called by muse, mutect2, varscan2
- TJP1 | c.2504C>T p.T835M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs752322243, COSV62046872; called by muse, mutect2, varscan2
- TM2D1 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99623961; called by muse, mutect2, varscan2
- TM4SF4 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs748715174, COSV100541821; called by muse, mutect2, varscan2
- TM4SF5 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99564791; called by muse, mutect2, varscan2
- TMCO6 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777697901, COSV52800661; called by muse, mutect2, varscan2
- TMEM104 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs754513415, COSV59109753; called by muse, mutect2, varscan2
- TMEM186 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs776766705, COSV99191176; called by muse, mutect2, varscan2
- TMEM198 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as rs951980082, COSV54719592; called by muse, mutect2, varscan2
- TMEM255A | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV100550523; called by muse, mutect2, varscan2
- TMEM258 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs780544004, COSV99607691; called by muse, mutect2, varscan2
- TMPRSS5 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs562297984, COSV100244555, COSV55425863; called by muse, mutect2, varscan2
- TNRC18 | c.4378C>T p.R1460C | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs371145281; called by muse, mutect2, varscan2
- TNRC18 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1343253173, COSV101259509; called by muse, mutect2
- TNRC6A | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 32/39 reads (82%) | catalogued as COSV59363872; called by muse, mutect2, varscan2
- TNS3 | c.3550G>A p.A1184T | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as rs375685287; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 55/98 reads (56%) | catalogued as rs587780067; called by pindel, varscan2
- TPCN1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.624); catalogued as rs757630299, COSV100136297, COSV100136978; called by muse, mutect2, varscan2
- TPCN1 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs200644632, COSV59237196; called by muse, mutect2, varscan2
- TPH2 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs147025898, CM109150, COSV61592994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPP2 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101060385; called by muse, mutect2, varscan2
- TRAF2 | c.26del p.P9Lfs*77 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs748531430; called by mutect2, pindel, varscan2
- TRAF3IP2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1352832056, COSV100389837; called by muse, mutect2, varscan2
- TRAM1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs545605500, COSV51599068; called by muse, mutect2, varscan2
- TRANK1 | c.7717C>T p.R2573W | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs767126712, COSV57165302; called by muse, mutect2, varscan2
- TRAPPC8 | c.3148T>G p.L1050V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99351795; called by muse, mutect2, varscan2
- TRDN | c.62dup p.N21Kfs*49 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | catalogued as rs774958537; called by mutect2, pindel, varscan2
- TRIM11 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.166); catalogued as COSV99488841; called by muse, mutect2, varscan2
- TRIM38 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs755536630, COSV100837624; called by muse, mutect2, varscan2
- TRIOBP | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 72/510 reads (14%) | catalogued as rs371412957; called by muse, varscan2
- TRPA1 | c.2017dup p.T673Nfs*9 | Frame Shift Ins (INS) | VAF 34/62 reads (55%) | catalogued as rs748693374; called by mutect2, varscan2
- TRPM2 | c.3773C>A p.P1258H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100309178; called by muse, mutect2, varscan2
- TRPM4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162091985, COSV53267856; called by muse, mutect2, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 52/60 reads (87%) | catalogued as rs752121179, COSV54531581; called by mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 47/118 reads (40%) | catalogued as rs760253164; called by pindel, varscan2
- TTI1 | c.2708T>C p.L903P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100989719; called by muse, varscan2
- TTLL8 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs747581157, COSV56726768, COSV56727584; called by muse, mutect2, varscan2
- TTN | c.20432G>A p.R6811H (on ENST00000591111; = p.R5884H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | PolyPhen possibly damaging (0.46); catalogued as rs768531006, COSV100624757; called by muse, mutect2, varscan2
- TULP4 | c.4048G>A p.V1350I | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as rs140677029; called by muse, mutect2, varscan2
- TXK | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs190691703, COSV99972728; called by muse, mutect2, varscan2
- TYMP | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99329603, COSV99329740; called by muse, mutect2, varscan2
- UBC | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as COSV100299085, COSV60059522; called by muse, varscan2
- UBE2B | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs1351686714, COSV54760673, COSV54761260; called by muse, mutect2, varscan2
- UBE2S | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1350509514, COSV52741132; called by muse, mutect2, varscan2
- UBN1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 83/110 reads (75%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs200541080; called by muse, mutect2, varscan2
- UCKL1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV100700560; called by muse, mutect2, varscan2
- UNC13C | c.6173C>T p.T2058M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs201637437; called by muse, mutect2, varscan2
- URGCP | c.779C>T p.A260V (on ENST00000453200 / NM_001077663.3; = p.A251V on NM_017920.4) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs376910575; called by muse, mutect2, varscan2
- USH2A | c.10886G>T p.G3629V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100240276, COSV56329090; called by muse, mutect2, varscan2
- VCAN | c.2620G>T p.A874S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV54105327, COSV99426894; called by muse, mutect2, varscan2
- VGLL4 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 125/150 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56077469; called by muse, mutect2, varscan2
- VPS26C | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99898662; called by muse, mutect2, varscan2
- WDR44 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99561848; called by muse, mutect2, varscan2
- WNT3A | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs142644449; called by muse, mutect2, varscan2
- XAB2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as rs546488334, COSV100601833; called by muse, mutect2, varscan2
- XKRX | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 21/24 reads (88%) | catalogued as COSV100139782; called by muse, mutect2, varscan2
- ZBTB34 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs576828106, COSV100043928; called by muse, mutect2, varscan2
- ZC3H3 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs778734040, COSV52787462; called by muse, mutect2, varscan2
- ZFC3H1 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs762379207, COSV66430154; called by muse, mutect2, varscan2
- ZFYVE26 | c.4198G>A p.V1400I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs187616174; called by muse, mutect2, varscan2
- ZHX3 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs771931047, COSV100476547; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1624del p.T542Lfs*27 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs757603403; called by mutect2, pindel, varscan2
- ZNF107 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs201478920, COSV61329500; called by muse, mutect2, varscan2
- ZNF12 | c.892G>A p.E298K (on ENST00000405858 / NM_016265.4; = p.E260K on NM_006956.3) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs780833245, COSV100703834; called by muse, mutect2, varscan2
- ZNF12 | c.472G>A p.G158R (on ENST00000405858 / NM_016265.4; = p.G120R on NM_006956.3) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.53); PolyPhen probably damaging (1); catalogued as COSV100703837; called by muse, mutect2, varscan2
- ZNF160 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs149621354; called by muse, mutect2, varscan2
- ZNF250 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99481024; called by muse, mutect2, varscan2
- ZNF254 | c.159T>C p.G53= | Splice Region (SNP) | VAF 53/103 reads (51%) | catalogued as COSV100298274; called by muse, mutect2, varscan2
- ZNF266 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.566); catalogued as rs887823834, COSV100749429; called by muse, mutect2, varscan2
- ZNF449 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV100203040; called by muse, mutect2, varscan2
- ZNF557 | c.1247C>T p.T416M (on ENST00000414706 / NM_001044388.2; = p.T423M on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs747902079, COSV53273523; called by muse, mutect2
- ZNF585B | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756197842, COSV57214785; called by muse, mutect2, varscan2
- ZNF777 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56096276; called by muse, mutect2, varscan2
- ZNF804A | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765819874, COSV56437566; called by muse, mutect2, varscan2
- ZNF835 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 69/80 reads (86%) | catalogued as COSV101606394; called by muse, mutect2, varscan2
- ACOT6 | c.600del p.K200Nfs*? | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- AGRN | c.1880del p.P627Rfs*105 | Frame Shift Del (DEL) | VAF 15/25 reads (60%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.2029del p.M677Cfs*33 | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | called by mutect2, pindel, varscan2
- AKAP12 | c.4382del p.N1461Mfs*26 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD34B | c.1096del p.A366Qfs*26 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.2150del p.P717Lfs*79 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- C1orf159 | c.836del p.P279Lfs*2 | Frame Shift Del (DEL) | VAF 73/127 reads (57%) | called by mutect2, pindel, varscan2
- CDC7 | c.572del p.K191Sfs*5 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 36/91 reads (40%) | called by mutect2, varscan2
- CEP250 | c.2653del p.M885Wfs*5 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- CEP350 | c.4969del p.T1657Lfs*9 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | called by mutect2, pindel, varscan2
- CH25H | c.154dup p.C52Lfs*25 | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.1234del p.L412Wfs*153 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- CILP2 | c.3107del p.P1036Hfs*17 | Frame Shift Del (DEL) | VAF 35/77 reads (45%) | called by mutect2, varscan2
- CLDN6 | c.567del p.S190Pfs*70 | Frame Shift Del (DEL) | VAF 68/119 reads (57%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 40/78 reads (51%) | called by mutect2, pindel, varscan2
- DMD | c.8284dup p.I2762Nfs*10 | Frame Shift Ins (INS) | VAF 53/79 reads (67%) | called by mutect2, pindel, varscan2
- DMXL1 | c.1381del p.M461Wfs*44 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- DVL1 | c.1593del p.W532Gfs*142 (on ENST00000378888 / NM_001330311.2; = p.W507Gfs*142 on NM_004421.3) | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- DYNC2H1 | c.1195del p.I399* | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- EPC2 | c.207del p.E70Rfs*39 | Frame Shift Del (DEL) | VAF 32/41 reads (78%) | called by mutect2, varscan2
- GPR135 | c.722_724del p.S241del | In Frame Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- GXYLT1 | c.573dup p.L192Tfs*3 | Frame Shift Ins (INS) | VAF 58/146 reads (40%) | called by pindel, varscan2
- HTT | c.8886del p.F2962Lfs*23 | Frame Shift Del (DEL) | VAF 38/57 reads (67%) | called by mutect2, pindel, varscan2
- INPP4B | c.2456_2459del p.K819Mfs*2 | Frame Shift Del (DEL) | VAF 46/65 reads (71%) | called by pindel, varscan2
- IQCH | c.2222del p.X741_splice | Splice Site (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- JMJD1C | c.2107_2108del p.L703Yfs*3 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- KDM6A | c.2717del p.N906Mfs*31 | Frame Shift Del (DEL) | VAF 36/38 reads (95%) | called by mutect2, varscan2
- KHSRP | c.731dup p.A245Gfs*13 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- KLRC2 | c.29_32del p.E10Gfs*31 | Frame Shift Del (DEL) | VAF 47/104 reads (45%) | called by mutect2, pindel, varscan2
- KLRC3 | c.29_32del p.E10Gfs*31 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, varscan2
- LRP1 | c.3686dup p.H1230Afs*28 | Frame Shift Ins (INS) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- LRP1 | c.4468del p.E1490Rfs*80 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1847_1848del p.K616Rfs*172 | Frame Shift Del (DEL) | VAF 21/30 reads (70%) | called by mutect2, pindel, varscan2
- MEST | c.825del p.I276Ffs*11 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- MORN4 | c.272del p.N91Mfs*4 | Frame Shift Del (DEL) | VAF 53/84 reads (63%) | called by mutect2, pindel, varscan2
- NEXN | c.717del p.E240Nfs*8 | Frame Shift Del (DEL) | VAF 44/75 reads (59%) | called by mutect2, pindel, varscan2
- OR2M4 | c.125dup p.N42Kfs*70 | Frame Shift Ins (INS) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- P2RY13 | c.468del p.K156Nfs*26 | Frame Shift Del (DEL) | VAF 14/22 reads (64%) | called by mutect2, pindel, varscan2
- PFKL | c.1841_1843del p.K614del | In Frame Del (DEL) | VAF 44/94 reads (47%) | called by pindel, varscan2
- PIK3C2B | c.3959_3962del p.I1320Sfs*7 | Frame Shift Del (DEL) | VAF 32/44 reads (73%) | called by pindel, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- POLR2A | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PRKG2 | c.1294_1295dup p.E433Wfs*3 | Frame Shift Ins (INS) | VAF 47/64 reads (73%) | called by mutect2, varscan2
- PRMT9 | c.211_212del p.F71Qfs*4 | Frame Shift Del (DEL) | VAF 31/53 reads (58%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.3572dup p.K1192Qfs*11 | Frame Shift Ins (INS) | VAF 10/96 reads (10%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4800del p.E1601Sfs*18 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- RGR | c.60del p.M21Wfs*16 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- RRBP1 | c.345del p.I116Lfs*41 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | called by mutect2, pindel, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, varscan2
- SCFD1 | c.938dup p.N313Kfs*6 | Frame Shift Ins (INS) | VAF 23/117 reads (20%) | called by mutect2, pindel, varscan2
- SLC10A5 | c.991dup p.T331Nfs*3 | Frame Shift Ins (INS) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- SLC27A4 | c.862del p.L288Sfs*19 | Frame Shift Del (DEL) | VAF 50/79 reads (63%) | called by mutect2, pindel, varscan2
- SYCP2 | c.2548del p.S850Afs*5 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- SYNE2 | c.14348del p.F4783Sfs*10 | Frame Shift Del (DEL) | VAF 38/87 reads (44%) | called by mutect2, pindel, varscan2
- TBRG1 | c.882dup p.G295Wfs*29 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- TMEM50A | c.426del p.F142Lfs*20 | Frame Shift Del (DEL) | VAF 41/72 reads (57%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.275del p.P92Lfs*6 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- TRAV40 | c.258del p.I87Lfs*2 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | called by mutect2, pindel, varscan2
- TRIM55 | c.1089_1092del p.T364Sfs*46 | Frame Shift Del (DEL) | VAF 41/75 reads (55%) | called by mutect2, pindel, varscan2
- TRPM1 | c.1017_1020del p.K339Nfs*21 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by pindel, varscan2
- TSGA10 | c.1468del p.M490Wfs*47 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- UBB | c.570del p.D191Tfs*35 | Frame Shift Del (DEL) | VAF 75/121 reads (62%) | called by mutect2, pindel, varscan2
- UBE2J2 | c.201dup p.P68Sfs*21 | Frame Shift Ins (INS) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- USH2A | c.14160del p.A4721Pfs*25 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- VPS13A | c.3068C>A p.P1023Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.05); called by muse, mutect2
- ZNF800 | c.267del p.K89Nfs*17 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- ACE | c.2277G>A p.P759= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs199715246, COSV99327527; called by muse, varscan2
- ACP5 | c.315C>T p.Y105= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs2229530; called by muse, mutect2, varscan2
- ADAMTS14 | c.315C>T p.S105= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV100941787; called by muse, mutect2, varscan2
- ADAMTS2 | c.3120C>T p.Y1040= | Silent (SNP) | VAF 75/164 reads (46%) | catalogued as rs749365337, COSV52387098, COSV99283822; called by muse, mutect2, varscan2
- ADAMTS20 | c.120C>T p.Y40= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV67140216; called by muse, mutect2, varscan2
- ADCY6 | c.2865C>T p.D955= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs753383547, COSV57168631; called by muse, mutect2, varscan2
- ADGRA1 | c.474C>T p.Y158= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs759608334, COSV66926921; called by muse, mutect2, varscan2
- ADGRB1 | c.1857C>T p.D619= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs565251569, COSV100030173; called by muse, mutect2, varscan2
- ADGRE2 | c.237C>T p.C79= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs767079042, COSV59693934; called by muse, mutect2, varscan2
- ADGRG6 | c.2457G>A p.T819= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as rs371011778; called by muse, mutect2, varscan2
- AFF2 | c.2907G>A p.S969= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as rs781838895, COSV99665638; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGRN | c.1407C>T p.L469= | Silent (SNP) | VAF 71/86 reads (83%) | catalogued as rs757288952, COSV101039012; called by muse, mutect2, varscan2
- ALOX15 | c.1140G>A p.P380= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as rs142441164, COSV99541648; called by muse, mutect2, varscan2
- ANXA2R | c.222T>C p.S74= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100148715; called by muse, mutect2, varscan2
- AP1M1 | c.1140C>T p.F380= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs1386067992, COSV52229567; called by muse, mutect2, varscan2
- APC | c.7491G>A p.S2497= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs776327733, COSV99969475; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAF | c.1569C>T p.G523= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99283404; called by muse, mutect2
- ARAP3 | c.45G>A p.T15= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs567176182, COSV53355600; called by muse, mutect2, varscan2
- ARHGAP11A | c.2526C>T p.V842= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100276904; called by muse, mutect2, varscan2
- ARL6IP5 | c.237G>C p.G79= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV99833024; called by muse, mutect2, varscan2
- ASGR1 | c.798C>T p.D266= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV52648650; called by muse, mutect2, varscan2
- ATAD5 | c.4365C>T p.D1455= | Silent (SNP) | VAF 45/56 reads (80%) | catalogued as COSV100430153; called by muse, mutect2, varscan2
- ATMIN | c.1195C>T p.L399= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100214744; called by muse, mutect2, varscan2
- ATN1 | c.1104G>A p.A368= | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as rs782152586, COSV100755741, COSV63112208; called by muse, mutect2, varscan2
- ATP6V0B | c.309C>T p.Y103= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as rs752164497, COSV99356595; called by muse, mutect2, varscan2
- AXL | c.330C>T p.S110= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs764751950, COSV99997029; called by muse, mutect2, varscan2
- BICRA | c.4677C>A p.T1559= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs540732449, COSV101194441; called by muse, mutect2, varscan2
- BRD4 | c.1401C>T p.A467= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs774896276, COSV54596663; called by muse, mutect2, varscan2
- BRPF1 | c.48G>A p.A16= | Silent (SNP) | VAF 39/45 reads (87%) | catalogued as rs757099971, COSV100121383; called by muse, mutect2, varscan2
- C21orf62 | c.267G>A p.A89= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as rs751393654, COSV66672086; called by muse, mutect2, varscan2
- CAMK2G | c.810G>A p.P270= | Silent (SNP) | VAF 47/60 reads (78%) | catalogued as rs200186779; called by muse, mutect2, varscan2
- CAPN6 | c.849A>G p.R283= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV60694749; called by muse, mutect2, varscan2
- CAPRIN2 | c.951C>T p.I317= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1181936292, COSV99195599; called by muse, mutect2, varscan2
- CCDC73 | c.1509G>A p.S503= | Silent (SNP) | VAF 71/85 reads (84%) | catalogued as rs1014566922, COSV58798723; called by muse, mutect2, varscan2
- CD19 | c.732G>A p.T244= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV100218236; called by muse, mutect2, varscan2
- CD2BP2 | c.768G>A p.A256= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs928253789, COSV59769698; called by muse, mutect2, varscan2
- CD93 | c.1035C>T p.D345= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as rs368417861; called by muse, mutect2, varscan2
- CDC42BPB | c.732G>T p.S244= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV100775569; called by muse, varscan2
- CDC5L | c.1494C>T p.A498= | Silent (SNP) | VAF 45/50 reads (90%) | catalogued as rs371297756, COSV101015145; called by muse, mutect2, varscan2
- CDH22 | c.1347C>T p.G449= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as rs1035352597, COSV100952961; called by muse, mutect2, varscan2
- CDON | c.3333C>T p.C1111= | Silent (SNP) | VAF 37/47 reads (79%) | catalogued as COSV99701812; called by muse, mutect2, varscan2
- CELSR1 | c.8475G>A p.S2825= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs148280744; called by muse, mutect2, varscan2
- CHST13 | c.783C>T p.Y261= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as rs1429584183, COSV60042430; called by muse, mutect2, varscan2
- CHST3 | c.687C>T p.C229= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1214931622, COSV100910515; called by muse, mutect2, varscan2
- CILP2 | c.1635C>T p.A545= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs887620296, COSV52273201, COSV99364550; called by muse, mutect2, varscan2
- COL16A1 | c.2715G>A p.P905= | Silent (SNP) | VAF 42/48 reads (88%) | catalogued as rs762336003, COSV99595217; called by muse, mutect2, varscan2
- COL18A1 | c.4893C>T p.I1631= (on ENST00000359759 / NM_130444.3; = p.I1396= on NM_030582.4) | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs751253150, COSV60595220; called by muse, mutect2, varscan2
- CORO1C | c.900G>A p.P300= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs748283648, COSV54595503; called by muse, mutect2, varscan2
- CRACD | c.3261G>A p.P1087= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs142870169; called by mutect2, varscan2
- CRACDL | c.2133C>T p.A711= | Silent (SNP) | VAF 51/58 reads (88%) | catalogued as rs372457015; called by muse, mutect2, varscan2
- CRADD | c.153C>A p.L51= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100257766; called by muse, mutect2, varscan2
- CRB2 | c.2421C>T p.S807= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs764349689, COSV63506320; called by muse, mutect2, varscan2
- CSK | c.1239C>T p.P413= | Silent (SNP) | VAF 70/172 reads (41%) | catalogued as rs145089812; called by muse, mutect2, varscan2
- CTTNBP2 | c.4539G>A p.T1513= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs149265601, COSV50389718; called by muse, mutect2, varscan2
- CXADR | c.48C>T p.F16= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as rs376266997; called by muse, mutect2, varscan2
- CYP4F11 | c.1521C>T p.R507= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs774161991, COSV56126883, COSV99931035; called by muse, mutect2, varscan2
- DCAF15 | c.1038G>A p.L346= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs986121930, COSV99586367; called by muse, mutect2, varscan2
- DHCR7 | c.507G>A p.S169= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as rs138185442, COSV100832017; called by muse, mutect2, varscan2
- DMBT1 | c.2904G>A p.S968= | Silent (SNP) | VAF 67/124 reads (54%) | catalogued as rs549068481, COSV100352792; called by muse, mutect2, varscan2
- DMRTB1 | c.741C>T p.G247= | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as COSV65114064; called by muse, mutect2, varscan2
- DNER | c.2058C>T p.I686= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as rs752912056, COSV100519799; called by muse, mutect2, varscan2
- DPYSL4 | c.207C>T p.G69= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs200948541, COSV58305707; called by muse, mutect2, varscan2
- DRC7 | c.1809C>T p.D603= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs201411909, COSV100395863; called by muse, varscan2
- DSC3 | c.1968C>T p.A656= | Silent (SNP) | VAF 34/46 reads (74%) | catalogued as rs141990544; called by muse, mutect2, varscan2
- ESPNL | c.933G>A p.A311= | Silent (SNP) | VAF 33/44 reads (75%) | catalogued as rs376907113, COSV58039715; called by muse, mutect2, varscan2
- EWSR1 | c.978C>T p.S326= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV58425184; called by muse, varscan2
- FAM117B | c.1542C>T p.L514= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs938931875, COSV57419677, COSV57423091; called by muse, mutect2, varscan2
- FAM214A | c.2706C>T p.A902= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as rs757013269, COSV99958386; called by muse, mutect2, varscan2
- FHOD1 | c.1248T>G p.A416= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV99264404; called by muse, mutect2, varscan2
- FMO4 | c.558C>T p.R186= | Silent (SNP) | VAF 42/49 reads (86%) | catalogued as rs1053562450, COSV63000778; called by muse, mutect2, varscan2
- FNDC1 | c.3030C>T p.V1010= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV99796435; called by muse, mutect2, varscan2
- FRMPD1 | c.1767G>A p.A589= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as rs766018914, COSV100899663, COSV66701239; called by muse, mutect2, varscan2
- FUT1 | c.294G>A p.T98= | Silent (SNP) | VAF 38/238 reads (16%) | catalogued as COSV100038230; called by muse, mutect2, varscan2
- GCN1 | c.2970G>A p.T990= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs750201105, COSV100325834; called by muse, mutect2, varscan2
- GOLGA6A | c.1053G>A p.A351= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1172288482, COSV99297333; called by mutect2, varscan2
- GPR119 | c.285G>A p.T95= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as rs759367657, COSV99358698; called by muse, varscan2
- GRIN2A | c.3636G>A p.T1212= | Silent (SNP) | VAF 74/83 reads (89%) | catalogued as rs765614514, COSV58030376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSDMC | c.1239G>A p.L413= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs767384962, COSV52696654, COSV99416334; called by muse, mutect2, varscan2
- HIVEP1 | c.7980G>A p.T2660= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs563520519, COSV101045591; called by muse, varscan2
- HTR2B | c.828G>A p.S276= | Silent (SNP) | VAF 54/69 reads (78%) | catalogued as rs139956541; called by muse, mutect2, varscan2
- INHBB | c.813G>A p.S271= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs778038309, COSV54677428; called by muse, mutect2, varscan2
- IPO4 | c.1806G>A p.A602= | Silent (SNP) | VAF 103/185 reads (56%) | catalogued as rs371519200; called by muse, mutect2, varscan2
- IQCA1 | c.138C>T p.Y46= | Silent (SNP) | VAF 54/72 reads (75%) | catalogued as rs748364665, COSV99610225; called by muse, mutect2, varscan2
- IQGAP3 | c.3762C>T p.C1254= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV63253268; called by muse, mutect2, varscan2
- IRX4 | c.375C>T p.Y125= | Silent (SNP) | VAF 114/285 reads (40%) | catalogued as rs145620050; called by muse, mutect2, varscan2
- KAT2A | c.1851C>T p.Y617= | Silent (SNP) | VAF 39/54 reads (72%) | catalogued as rs782757718, COSV99288439; called by muse, mutect2, varscan2
- KLF7 | c.672C>T p.N224= | Silent (SNP) | VAF 34/51 reads (67%) | catalogued as rs201005804, COSV58743383; called by muse, mutect2, varscan2
- KLHL22 | c.1530C>T p.D510= | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as rs759003865, COSV100185753; called by muse, mutect2, varscan2
- LAMA2 | c.4803G>A p.P1601= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs766521929, COSV101370745; called by muse, mutect2, varscan2
- LAMP3 | c.375C>T p.V125= | Silent (SNP) | VAF 66/84 reads (79%) | catalogued as rs748363578, COSV99660717; called by muse, mutect2, varscan2
- LILRB2 | c.1605C>T p.A535= | Silent (SNP) | VAF 76/155 reads (49%) | catalogued as rs373123561; called by muse, mutect2, varscan2
- LMNB2 | c.1095C>T p.D365= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs990065554, COSV57587565; called by muse, mutect2, varscan2
- LONP1 | c.2121C>T p.S707= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs376954188; called by muse, mutect2, varscan2
- LRRC56 | c.834C>T p.P278= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as rs781354927, COSV99530667; called by muse, mutect2, varscan2
- LTBP2 | c.4620C>T p.G1540= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs147213897; called by mutect2, varscan2
- LURAP1 | c.348C>T p.G116= | Silent (SNP) | VAF 57/71 reads (80%) | catalogued as rs755400846, COSV100915135; called by muse, mutect2, varscan2
- MAGI2 | c.411G>A p.T137= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs149568072, COSV100835566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAML3 | c.3273C>T p.D1091= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs377696242, COSV72209030; called by muse, mutect2, varscan2
- MAP2K7 | c.138G>A p.P46= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs753123405, COSV101209119; called by muse, mutect2, varscan2
- MAP3K9 | c.2262C>T p.L754= (on ENST00000554752 / NM_001284230.1; = p.L768= on NM_033141.4) | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs1162591042, COSV67120112; called by muse, mutect2, varscan2
- MAST3 | c.2307C>T p.P769= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs185148853; called by muse, mutect2, varscan2
126 further variants in this file (0 protein-altering or splice-affecting, 112 silent, 14 other) are not listed here.
